Somatic mutation profile of tumor specimen TCGA-56-8307-01A (aliquot TCGA-56-8307-01A-11D-2293-08) from TCGA case TCGA-56-8307, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.9 years (20,411 days).
Specimen TCGA-56-8307-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16850b13-91a0-4e40-8210-1570c5ea6432.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8307-10A (Blood Derived Normal), aliquot TCGA-56-8307-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af757cb1-0d01-4828-8370-5ad307f28849

The open-access MAF lists 456 somatic variants for this specimen: 361 protein-altering or splice-affecting, 86 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 303, Silent 86, Nonsense Mutation 20, Splice Site 16, Frame Shift Del 12, Splice Region 7, RNA 5, Intron 2, Frame Shift Ins 1, In Frame Del 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 40/76 reads (53%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARD | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100991909; called by muse, mutect2, varscan2
- ABCD2 | c.1237-1G>T p.X413_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as rs779299135, COSV100429520; called by muse, mutect2, varscan2
- ACOT11 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs1471738871, COSV100650629; called by muse, mutect2, varscan2
- ACSM1 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99533029; called by muse, mutect2, varscan2
- ADAMTS1 | c.1370A>G p.N457S | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as COSV99536194; called by muse, mutect2, varscan2
- ADD3 | c.568-1G>A p.X190_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99523456; called by muse, mutect2, varscan2
- ADD3 | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV99523458; called by muse, mutect2, varscan2
- ADGRG4 | c.3882G>T p.L1294F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV99795642; called by muse, mutect2, varscan2
- AGPAT5 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99576494; called by muse, mutect2, varscan2
- AGRN | c.5221G>T p.G1741C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV101038890; called by muse, mutect2
- AHNAK | c.12529G>T p.V4177L | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.269); catalogued as COSV99947732; called by muse, mutect2, varscan2
- AHRR | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs758409180, COSV100327387; called by mutect2, varscan2
- AIMP1 | c.684G>C p.M228I | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100786175; called by muse, mutect2, varscan2
- AIRE | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1385283838, COSV99381180; called by muse, mutect2, varscan2
- AK1 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99802405; called by muse, mutect2, varscan2
- AKT2 | c.240G>T p.W80C | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60908226; called by muse, mutect2, varscan2
- AL031777.2 | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV100587188; called by muse, mutect2, varscan2
- ALDH16A1 | c.1438-1G>T p.X480_splice | Splice Site (SNP) | VAF 78/252 reads (31%) | catalogued as COSV99512949; called by muse, mutect2, varscan2
- ALDH16A1 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99512953; called by muse, mutect2, varscan2
- ALDH1A2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV51087136, COSV99990775; called by muse, mutect2, varscan2
- ALPK2 | c.4799C>A p.P1600H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100864436; called by muse, mutect2, varscan2
- ANGPTL4 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1426629342, COSV100035151; called by muse, mutect2, varscan2
- ANKFN1 | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100593569; called by muse, mutect2, varscan2
- ANO4 | c.1661C>T p.A554V (on ENST00000392977 / NM_001286615.2; = p.A519V on NM_178826.4) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100152991; called by muse, mutect2, varscan2
- ANO5 | c.2556G>T p.W852C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100201905; called by muse, mutect2, varscan2
- AOAH | c.1678C>G p.P560A | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51747887, COSV99332923; called by muse, mutect2, varscan2
- AOX1 | c.2096A>T p.D699V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV101022010; called by muse, mutect2, varscan2
- AP3D1 | c.3400A>C p.S1134R | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV100642724; called by muse, mutect2, varscan2
- AP3D1 | c.1944G>T p.E648D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV100642727; called by muse, mutect2, varscan2
- APPBP2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as rs762177326, COSV99319707; called by muse, mutect2, varscan2
- ARSF | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100839522; called by muse, mutect2, varscan2
- ASB9 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100995522; called by muse, mutect2, varscan2
- ASCC3 | c.3685A>T p.N1229Y | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100225825, COSV61228512; called by muse, mutect2, varscan2
- ASTN1 | c.3807C>A p.S1269R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100706916; called by muse, mutect2, varscan2
- ASXL1 | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100039480; called by muse, mutect2, varscan2
- ASXL3 | c.6218C>T p.T2073M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs769078252, COSV52481944; called by muse, mutect2, varscan2
- B3GALT2 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100813610; called by muse, mutect2, varscan2
- BCAS3 | c.2764C>G p.L922V (on ENST00000390652 / NM_001353144.2; = p.L907V on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.931); catalogued as COSV101176020; called by muse, mutect2, varscan2
- BCLAF3 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV100503306; called by muse, mutect2, varscan2
- BEND2 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101192037; called by muse, mutect2, varscan2
- BIN2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs748235442, COSV57208557; called by muse, mutect2, varscan2
- BPIFB6 | c.463A>T p.K155* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV62755529; called by muse, mutect2, varscan2
- BUB1 | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100241295; called by muse, mutect2, varscan2
- C10orf99 | c.220G>T p.V74L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100929357; called by muse, mutect2, varscan2
- C1orf127 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.273); catalogued as rs758927695, COSV100983489; called by muse, mutect2, varscan2
- C1orf87 | c.966C>A p.D322E | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100967020, COSV100967100; called by muse, mutect2, varscan2
- C7 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV57473700; called by muse, mutect2, varscan2
- CACNA2D2 | c.3241G>C p.E1081Q (on ENST00000479441 / NM_001174051.3; = p.E1074Q on NM_006030.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.277); catalogued as COSV99817785; called by muse, mutect2, varscan2
- CALR3 | c.738C>A p.D246E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99522206; called by muse, mutect2, varscan2
- CAMK1G | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99151701; called by muse, mutect2, varscan2
- CAPN1 | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99658698; called by muse, mutect2, varscan2
- CAPN10 | c.1951A>G p.I651V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs371891730; called by muse, mutect2, varscan2
- CAPN11 | c.1865T>A p.M622K | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV101291891; called by muse, mutect2, varscan2
- CAPN13 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780935684, COSV54428827, COSV99700293; called by muse, mutect2, varscan2
- CAPN5 | c.470A>T p.Y157F (on ENST00000456580; = p.Y117F on NM_004055.5) | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99582226; called by muse, mutect2, varscan2
- CAPRIN1 | c.1721A>G p.H574R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100403931; called by muse, mutect2, varscan2
- CBLN2 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99504421; called by muse, mutect2, varscan2
- CCDC178 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100285062; called by muse, mutect2
- CCDC178 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV55765480; called by muse, mutect2, varscan2
- CCHCR1 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV100883881; called by muse, mutect2, varscan2
- CDH10 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 42/127 reads (33%) | catalogued as COSV100051703; called by muse, mutect2, varscan2
- CDH12 | c.841T>A p.S281T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs983040903, COSV101202659; called by muse, mutect2, varscan2
- CDH2 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52298466; called by muse, mutect2, varscan2
- CEACAM5 | c.98C>G p.T33S | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV99703947; called by muse, mutect2, varscan2
- CENPE | c.7097A>T p.N2366I | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99478096; called by muse, mutect2, varscan2
- CEP162 | c.4036A>T p.T1346S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100002866; called by muse, mutect2, varscan2
- CER1 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV101097831; called by muse, mutect2, varscan2
- CER1 | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV66603156; called by muse, mutect2, varscan2
- CFHR5 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV99888881; called by muse, mutect2, varscan2
- CGAS | c.1309C>G p.H437D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943676, COSV64807997; called by muse, mutect2, varscan2
- CHRD | c.1700A>G p.Y567C | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99200455; called by muse, mutect2, varscan2
- CLCA1 | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99322462, COSV99322914; called by muse, mutect2, varscan2
- CNGB3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100182089, COSV60693774; called by muse, mutect2, varscan2
- CNNM1 | c.1365G>C p.E455D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100763877, COSV63200069; called by muse, mutect2, varscan2
- COL11A1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100616793, COSV100618457; called by muse, mutect2, varscan2
- COL14A1 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV99919431; called by muse, mutect2, varscan2
- COL19A1 | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV59567226; called by muse, mutect2, varscan2
- COL2A1 | c.3815C>A p.P1272H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476637; called by muse, mutect2, varscan2
- COPS7B | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.204); catalogued as COSV100602233; called by muse, mutect2, varscan2
- CPED1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100120826, COSV100121222; called by muse, mutect2, varscan2
- CRISP1 | c.750G>T p.*250Yext*11 | Nonstop Mutation (SNP) | VAF 43/150 reads (29%) | catalogued as rs756867160, COSV59993613; called by muse, mutect2, varscan2
- CSF3R | c.2227C>A p.Q743K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as COSV100117766, COSV58963519; called by muse, mutect2, varscan2
- CSMD3 | c.10827G>A p.L3609= (on ENST00000297405 / NM_001363185.1; = p.L3440= on NM_052900.3) | Splice Region (SNP) | VAF 20/93 reads (22%) | catalogued as COSV52174855, COSV99840019; called by muse, mutect2, varscan2
- CWH43 | c.827T>A p.L276H | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99893498; called by muse, mutect2, varscan2
- CWH43 | c.1778A>T p.Q593L | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.121); catalogued as COSV99893500; called by muse, mutect2, varscan2
- CXorf58 | c.216+1del | Frame Shift Del (DEL) | VAF 49/255 reads (19%) | catalogued as COSV101003124; called by mutect2, pindel, varscan2
- DCLK1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99711475; called by muse, mutect2, varscan2
- DDX23 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as COSV100339844, COSV104411620; called by muse, mutect2, varscan2
- DEFB115 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV101269311; called by muse, mutect2, varscan2
- DENND2A | c.2062C>G p.R688G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV52060875, COSV99326201; called by muse, mutect2, varscan2
- DMXL1 | c.7995A>T p.Q2665H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100224088; called by muse, mutect2, varscan2
- DNAH8 | c.8731G>A p.E2911K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100545635; called by muse, mutect2, varscan2
- DOK6 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101234532; called by muse, mutect2, varscan2
- DOLK | c.1463C>A p.A488D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.354); catalogued as COSV100455096; called by muse, mutect2, varscan2
- DSP | c.2986-1G>T p.X996_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | catalogued as COSV101131320; called by muse, mutect2, varscan2
- DST | c.11715A>C p.E3905D (on ENST00000361203 / NM_001374722.1; = p.E1493D on NM_015548.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV99756601; called by muse, mutect2
- DTX3L | c.547A>G p.R183G | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99950046; called by muse, mutect2, varscan2
- ENAM | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV101253130; called by muse, mutect2, varscan2
- ENPP3 | c.2129T>A p.I710N | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs757895652, COSV100717368; called by muse, mutect2, varscan2
- EPG5 | c.2968G>T p.A990S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99957390; called by muse, mutect2, varscan2
- EPHA2 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780924846, COSV100626138, COSV64452682; called by muse, mutect2, varscan2
- EPHA3 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100345638, COSV60696288, COSV60704066; called by muse, mutect2, varscan2
- EPHA6 | c.1207G>T p.V403F | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.599); catalogued as COSV101063173; called by muse, mutect2, varscan2
- ESPNL | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58036801; called by muse, mutect2
- EYA4 | c.580+1G>C p.X194_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100765948; called by muse, mutect2, varscan2
- FAT4 | c.11354T>C p.F3785S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100628786; called by muse, mutect2, varscan2
- FCGR2B | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV99375163; called by muse, mutect2, varscan2
- FCRL5 | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV100708988; called by muse, mutect2, varscan2
- FGA | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100120410; called by muse, mutect2, varscan2
- FLG | c.6489C>A p.H2163Q | Missense Mutation (SNP) | VAF 158/613 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV100911625, COSV64251643; called by muse, mutect2, varscan2
- FMN2 | c.5058G>C p.E1686D | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100145410, COSV100147484, COSV60426905; called by muse, mutect2, varscan2
- FOXG1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV100486850; called by muse, mutect2, varscan2
- FOXG1 | c.1300A>C p.M434L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100486851; called by muse, mutect2, varscan2
- FOXL2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD012524, COSV100374582; called by muse, mutect2, varscan2
- FRK | c.740A>T p.E247V | Missense Mutation (SNP) | VAF 89/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101606653; called by muse, mutect2, varscan2
- FRMPD2 | c.3915del p.T1306Qfs*27 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as COSV59716920; called by mutect2, pindel, varscan2
- FSTL5 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV100056171; called by muse, mutect2, varscan2
- FTMT | c.299A>T p.Y100F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV100360354; called by muse, mutect2, varscan2
- GABRA3 | c.1143+1G>T p.X381_splice | Splice Site (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100942798; called by muse, mutect2, varscan2
- GALNT13 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV101223140; called by muse, mutect2, varscan2
- GATAD2B | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100897885; called by muse, mutect2, varscan2
- GCA | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280580; called by muse, mutect2, varscan2
- GNAI2 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99807049; called by muse, mutect2, varscan2
- GNL3L | c.864-1G>T p.X288_splice | Splice Site (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100328413; called by muse, mutect2, varscan2
- GOLGA3 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV99206848; called by muse, mutect2, varscan2
- GPAM | c.1754T>G p.I585S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV100788240; called by muse, mutect2, varscan2
- GPLD1 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100015360; called by muse, mutect2, varscan2
- GPNMB | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs367885589, COSV51699874; called by muse, mutect2, varscan2
- GRIA1 | c.2520G>A p.K840= | Splice Region (SNP) | VAF 59/238 reads (25%) | catalogued as rs1376445849, COSV99600248; called by muse, mutect2, varscan2
- GRM5 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100552243; called by muse, mutect2, varscan2
- GRXCR1 | c.505A>T p.K169* | Nonsense Mutation (SNP) | VAF 76/222 reads (34%) | catalogued as COSV101295697, COSV67674477; called by muse, mutect2, varscan2
- HAGHL | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99284888; called by muse, mutect2, varscan2
- HEATR1 | c.142+1G>T p.X48_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100857203; called by muse, mutect2, varscan2
- HELB | c.2031T>A p.D677E | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99921941; called by muse, mutect2, varscan2
- HELB | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.893); catalogued as COSV99921942; called by muse, mutect2, varscan2
- HIF1A | c.2258A>G p.K753R | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV100048939; called by muse, mutect2, varscan2
- HMX3 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774114, COSV100774145; called by muse, mutect2, varscan2
- HOOK1 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100969120; called by muse, mutect2
- HOXC10 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.867); catalogued as rs758078495, COSV100329087; called by muse, mutect2, varscan2
- HOXC12 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99678748; called by muse, mutect2, varscan2
- HOXC13 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV99673421; called by muse, mutect2, varscan2
- HTR1A | c.1160G>T p.W387L | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100109106; called by muse, mutect2, varscan2
- HTR1A | c.979C>A p.R327S | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.313); catalogued as COSV100109108; called by muse, mutect2, varscan2
- HTT | c.9187G>C p.A3063P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61864521; called by muse, mutect2, varscan2
- IGKV1D-12 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs1379763260; called by mutect2, varscan2
- IGSF22 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100079828; called by muse, mutect2, varscan2
- IGSF9B | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100317769; called by muse, mutect2, varscan2
- INHBA | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 222/687 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.268); catalogued as COSV99637764; called by muse, mutect2, varscan2
- IQCK | c.247-1G>T p.X83_splice | Splice Site (SNP) | VAF 75/230 reads (33%) | catalogued as COSV100244902; called by muse, mutect2, varscan2
- IRGQ | c.227A>T p.N76I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100338168; called by muse, mutect2
- ITGB1 | c.2304G>C p.K768N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171701; called by muse, mutect2, varscan2
- KDM6A | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100938241; called by muse, mutect2, varscan2
- KDM6A | c.2236G>T p.G746* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100938242; called by muse, mutect2, varscan2
- KERA | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV57131779, COSV99899459; called by muse, mutect2, varscan2
- KIT | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99854381; called by muse, mutect2, varscan2
- KLK15 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.734); catalogued as rs139684673; called by muse, mutect2, varscan2
- KLRC1 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100760818; called by muse, mutect2, varscan2
- KRT19 | c.823-1G>C p.X275_splice | Splice Site (SNP) | VAF 19/127 reads (15%) | catalogued as COSV99563076; called by muse, mutect2, varscan2
- KRT34 | c.804C>A p.N268K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV101222640, COSV101222646, COSV67449796; called by muse, mutect2, varscan2
- LANCL3 | c.1021C>A p.H341N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101065653; called by muse, mutect2, varscan2
- LRRK2 | c.2403T>A p.N801K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as COSV100110322; called by muse, mutect2, varscan2
- LYST | c.8312C>G p.P2771R | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV101089614; called by muse, mutect2
- MAGEB4 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV100854707; called by muse, mutect2, varscan2
- MAGED2 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99514594; called by muse, mutect2
- MAML2 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV73264469; called by muse, varscan2
- MAML2 | c.1551del p.G518Afs*9 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as COSV73262847; called by pindel, varscan2
- MAML3 | c.3221G>C p.S1074T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV101558445; called by muse, mutect2, varscan2
- MAN2A1 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99811264; called by muse, mutect2, varscan2
- MAN2A1 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54859317; called by muse, mutect2, varscan2
- MAP1LC3C | c.114G>T p.P38= | Splice Region (SNP) | VAF 142/432 reads (33%) | catalogued as COSV100606529, COSV61804055; called by muse, mutect2, varscan2
- MCM6 | c.2120C>G p.S707C | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV99919099; called by muse, mutect2, varscan2
- METRNL | c.326G>T p.R109M | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100193725; called by muse, mutect2, varscan2
- MFN2 | c.1809G>T p.M603I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV99336798; called by muse, mutect2, varscan2
- MGLL | c.719G>A p.R240H (on ENST00000398104 / NM_001003794.2; = p.R250H on NM_007283.6) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs372843202; called by muse, mutect2, varscan2
- MLX | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99518963; called by muse, mutect2, varscan2
- MMP16 | c.1171A>G p.S391G | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV104378057, COSV99688574; called by muse, mutect2, varscan2
- MUC16 | c.31076A>G p.Y10359C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); catalogued as COSV101200043; called by muse, mutect2, varscan2
- MUC16 | c.28274T>A p.L9425Q | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.206); catalogued as COSV101200045; called by muse, mutect2, varscan2
- MXRA5 | c.4453G>T p.A1485S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV99477174; called by muse, mutect2, varscan2
- MXRA5 | c.2105C>G p.S702W | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99477177; called by muse, mutect2, varscan2
- MYH7 | c.4075C>A p.R1359S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs45451303, CM081704, COSV100806166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.5185A>G p.T1729A | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV101238430; called by muse, mutect2, varscan2
- NALCN | c.1435-1G>T p.X479_splice | Splice Site (SNP) | VAF 48/83 reads (58%) | catalogued as COSV99215492; called by muse, mutect2, varscan2
- NAT10 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140131; called by muse, mutect2, varscan2
- NBEA | c.7682C>A p.P2561Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100080735; called by muse, mutect2, varscan2
- NEDD9 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV101060854; called by muse, mutect2, varscan2
- NEK5 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1355705834, COSV100839242; called by muse, mutect2, varscan2
- NHLRC1 | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100513491; called by muse, mutect2, varscan2
- NHS | c.4870C>T p.R1624C | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238527746, COSV101196634; called by muse, mutect2, varscan2
- NOBOX | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV99779479; called by muse, mutect2, varscan2
- NSMAF | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 51/164 reads (31%) | catalogued as COSV99232951; called by muse, mutect2, varscan2
- NUP62CL | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100991031; called by muse, mutect2
- OBSL1 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs755748297, COSV54713415; called by muse, mutect2
- OR10S1 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV101602478; called by muse, mutect2, varscan2
- OR2C3 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100825710; called by muse, mutect2, varscan2
- OR2G3 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV60682072; called by muse, mutect2, varscan2
- OR2L8 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs374677724; called by muse, mutect2, varscan2
- OR2M2 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100677237; called by muse, mutect2, varscan2
- OR2T11 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100424839; called by muse, mutect2, varscan2
- OR4C16 | c.757A>G p.I253V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs774927306, COSV100114078; called by muse, mutect2, varscan2
- OR4K5 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100262405; called by muse, mutect2, varscan2
- OR4M1 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100271240; called by muse, mutect2, varscan2
- OR52K1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100297668; called by muse, mutect2, varscan2
- OR52R1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1197930232, COSV100617733, COSV61887852; called by muse, mutect2, varscan2
- OR56A4 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100417582, COSV100417739; called by muse, mutect2, varscan2
- OR5K4 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 175/354 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs201921508, COSV100721354; called by muse, mutect2, varscan2
- OR6B2 | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99401476; called by muse, mutect2
- OR6K6 | c.345T>A p.S115R (on ENST00000368144; = p.S91R on NM_001005184.1) | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100933747; called by muse, mutect2, varscan2
- OR6X1 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100020546; called by muse, mutect2, varscan2
- OR8G5 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100422449; called by muse, mutect2, varscan2
- OR9G1 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100380258; called by muse, mutect2
- PAGE1 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101093962; called by muse, mutect2, varscan2
- PAPPA2 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.045); catalogued as rs1487227127, COSV100866810; called by muse, mutect2, varscan2
- PAX7 | c.729C>A p.D243E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100946826; called by muse, mutect2, varscan2
- PCDH18 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100787319, COSV61271351; called by muse, mutect2, varscan2
- PCDHA4 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV63545521, COSV63546348; called by muse, mutect2, varscan2
- PCDHB7 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs370716235, COSV99177027; called by muse, mutect2, varscan2
- PCDHGB6 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99539246, COSV99549731; called by muse, mutect2, varscan2
- PCLO | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV61671095; called by muse, mutect2, varscan2
- PGAP1 | c.1187G>C p.W396S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100698219; called by muse, mutect2, varscan2
- PHACTR3 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.03); catalogued as COSV100732676, COSV63024939; called by muse, mutect2, varscan2
- PIGS | c.1250G>C p.G417A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as COSV99256933; called by muse, mutect2, varscan2
- PKD1L1 | c.2983G>T p.V995L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs779114210, COSV56980851, COSV99219908; called by muse, mutect2, varscan2
- PLCE1 | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs772882305, COSV99595163; called by muse, mutect2, varscan2
- PLCE1 | c.4937G>A p.G1646E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99595171; called by muse, mutect2, varscan2
- PLCH1 | c.1807G>T p.D603Y (on ENST00000340059 / NM_001130960.2; = p.D615Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396910, COSV100397012, COSV58208727; called by muse, mutect2, varscan2
- PLK1 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100267253; called by muse, mutect2, varscan2
- PLPBP | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60240667; called by muse, mutect2, varscan2
- PLXNA4 | c.3700C>A p.L1234I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100324543; called by muse, mutect2, varscan2
- PLXNB2 | c.2432A>T p.E811V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.166); catalogued as COSV100834086; called by muse, mutect2, varscan2
- PPIP5K2 | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.071); catalogued as COSV100383903, COSV104395430; called by muse, mutect2, varscan2
- PPRC1 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99531712; called by muse, mutect2, varscan2
- PRRG3 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368110928, COSV100948644; called by muse, mutect2, varscan2
- PRSS35 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs769349887, COSV63801404; called by muse, mutect2, varscan2
- PRUNE2 | c.4661C>T p.S1554L | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100944656; called by muse, mutect2, varscan2
- PTCH2 | c.910A>T p.R304* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100942120; called by muse, mutect2, varscan2
- RALGAPA2 | c.2246G>C p.G749A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV52500558, COSV99173696; called by muse, mutect2, varscan2
- RASAL3 | c.2322C>A p.D774E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.875); catalogued as COSV99653277; called by muse, mutect2, varscan2
- RELCH | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.791); catalogued as COSV99902154; called by muse, mutect2, varscan2
- RGS12 | c.3619G>T p.G1207W | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122952; called by muse, mutect2, varscan2
- RIMS1 | c.1796G>T p.R599L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99327331; called by muse, mutect2, varscan2
- RIPK4 | c.250G>C p.V84L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100205002; called by muse, mutect2, varscan2
- RPH3A | c.769G>T p.A257S (on ENST00000389385 / NM_001143854.2; = p.A253S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.036); catalogued as COSV101231785, COSV66990050; called by muse, mutect2, varscan2
- RPS6KA5 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV100002662; called by muse, mutect2, varscan2
- RTL9 | c.686T>A p.M229K | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101511698; called by muse, mutect2, varscan2
- RTTN | c.5954G>T p.C1985F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV99732609; called by muse, mutect2, varscan2
- RUBCN | c.1803G>T p.R601S | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.581); catalogued as COSV99584144; called by muse, mutect2, varscan2
- RYR2 | c.9727T>C p.C3243R | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100770629; called by muse, mutect2, varscan2
- SCNN1G | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173152145, COSV100264239; called by muse, mutect2, varscan2
- SENP6 | c.2240A>G p.H747R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100894449; called by muse, mutect2, varscan2
- SEPTIN12 | c.724C>G p.R242G | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV99190712; called by muse, mutect2, varscan2
- SERPINB11 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV101236233; called by muse, mutect2, varscan2
- SEZ6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as COSV57980019; called by muse, mutect2, varscan2
- SF3B2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); catalogued as COSV100360881; called by muse, mutect2, varscan2
- SGCZ | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101170045, COSV66012001; called by muse, mutect2, varscan2
- SIAE | c.68-3del | Splice Region (DEL) | VAF 5/43 reads (12%) | catalogued as rs746169895; called by mutect2, pindel, varscan2
- SLC10A5 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101594258; called by muse, mutect2, varscan2
- SLC15A1 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100919490; called by muse, mutect2, varscan2
- SLC39A3 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99514213; called by muse, mutect2
- SLC41A1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs771501446, COSV100900520, COSV65651163; called by muse, mutect2, varscan2
- SLC5A5 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778105470, COSV99715098; called by muse, mutect2, varscan2
- SLC9C1 | c.1861A>T p.I621L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV99998078; called by muse, mutect2, varscan2
- SLITRK2 | c.821G>T p.R274M | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as COSV100157810; called by muse, mutect2, varscan2
- SLITRK2 | c.822G>T p.R274S | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV100158197, COSV59423320, COSV59427135; called by muse, mutect2, varscan2
- SLITRK2 | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.401); catalogued as COSV100157813, COSV59422866; called by muse, mutect2, varscan2
- SMG1 | c.9626T>C p.I3209T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV101246104; called by muse, mutect2, varscan2
- SMS | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101048085; called by muse, mutect2, varscan2
- SMYD3 | c.1155G>T p.M385I (on ENST00000490107 / NM_001375962.1; = p.M326I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100830756; called by muse, mutect2, varscan2
- SNX14 | c.1971G>T p.R657S (on ENST00000314673 / NM_001350535.1; = p.R604S on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100121582; called by muse, mutect2, varscan2
- SOGA3 | c.2129T>A p.L710Q | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV100846938; called by muse, mutect2, varscan2
- SORCS1 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99547027; called by muse, mutect2, varscan2
- SOX3 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.228); catalogued as COSV100983692, COSV100983728, COSV65167994; called by muse, mutect2, varscan2
- SOX30 | c.1444G>C p.V482L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99398485; called by muse, mutect2, varscan2
- SPHKAP | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.212); catalogued as COSV100764146; called by muse, mutect2, varscan2
- SREK1 | c.255A>T p.E85D | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); catalogued as COSV99398618; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.761T>G p.V254G | Missense Mutation (SNP) | VAF 17/136 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV100602763; called by muse, mutect2, varscan2
- STX10 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99460202; called by muse, mutect2, varscan2
- SUV39H1 | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as COSV100551780; called by muse, mutect2, varscan2
- SYNE1 | c.25568G>A p.R8523H (on ENST00000367255 / NM_182961.4; = p.R8475H on NM_033071.3) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs759577495, COSV99566274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D32 | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250461; called by muse, mutect2, varscan2
- TCP11L2 | c.1306T>C p.S436P | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV100135378; called by muse, mutect2, varscan2
- TEKT3 | c.1303C>A p.Q435K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as COSV100107115; called by muse, mutect2
- TENM1 | c.4397G>T p.G1466V | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100950165; called by muse, mutect2, varscan2
- TFDP3 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59537557; called by muse, mutect2, varscan2
- TFE3 | c.743T>A p.M248K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV100252596; called by muse, mutect2
- TG | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99601098; called by muse, mutect2, varscan2
- TLCD3B | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662454; called by muse, mutect2, varscan2
- TMEFF1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100614731; called by muse, mutect2, varscan2
- TMEM132D | c.2064G>T p.R688S | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV67160142, COSV67161670; called by muse, mutect2, varscan2
- TMEM132D | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV70601374, COSV99066495; called by muse, mutect2, varscan2
- TMEM245 | c.1224G>T p.W408C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV101002346; called by muse, mutect2, varscan2
- TMEM72 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs775485511, COSV101273529; called by muse, mutect2, varscan2
- TNFRSF17 | c.486T>A p.N162K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.154); catalogued as COSV99273258; called by muse, mutect2, varscan2
- TP53BP1 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as rs1341942710, COSV99780627; called by muse, mutect2, varscan2
- TPTE | c.665G>T p.R222L (on ENST00000618007 / NM_199261.4; = p.R204L on NM_199259.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs530503790; called by muse, mutect2, varscan2
- TRAPPC12 | c.1164C>T p.I388= | Splice Region (SNP) | VAF 69/272 reads (25%) | catalogued as rs751666792, COSV60845057; called by muse, mutect2, varscan2
- TRHDE | c.916G>T p.V306L | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.112); catalogued as COSV53848789; called by muse, mutect2, varscan2
- TRHDE | c.917T>A p.V306E | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.241); catalogued as COSV99671048; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV100709050; called by muse, mutect2, varscan2
- TRPM3 | c.2773-2A>G p.X925_splice (on ENST00000357533 / NM_001366142.2; = p.X768_splice on NM_020952.6) | Splice Site (SNP) | VAF 40/69 reads (58%) | catalogued as COSV100677492; called by muse, mutect2, varscan2
- TSHZ1 | c.2702A>T p.Q901L (on ENST00000580243 / NM_001308210.2; = p.Q856L on NM_005786.6) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100433727; called by muse, mutect2, varscan2
- TSSK1B | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.38); catalogued as COSV101181100; called by muse, mutect2, varscan2
- TTC37 | c.4208G>C p.W1403S | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706665; called by muse, mutect2, varscan2
- TTC7A | c.518-2A>T p.X173_splice | Splice Site (SNP) | VAF 52/138 reads (38%) | catalogued as COSV99766490; called by muse, mutect2, varscan2
- TTI1 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV100989643; called by muse, mutect2, varscan2
- TTLL4 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99293347; called by muse, varscan2
- TTN | c.90668A>G p.Y30223C (on ENST00000591111; = p.Y22799C on NM_003319.4) | Missense Mutation (SNP) | VAF 72/322 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV100615595; called by muse, mutect2, varscan2
- TTN | c.40967T>C p.V13656A (on ENST00000591111; = p.V6232A on NM_003319.4) | Missense Mutation (SNP) | VAF 39/132 reads (30%) | PolyPhen probably damaging (0.99); catalogued as rs775158152, COSV100615598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB1 | c.952C>G p.R318G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM090175, COSV99414079; called by muse, mutect2, varscan2
- TULP4 | c.3893A>G p.D1298G | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as COSV100893534; called by muse, mutect2, varscan2
- TXLNB | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100624992; called by muse, mutect2, varscan2
- UBA1 | c.2838G>C p.Q946H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100255747; called by muse, mutect2
- UBAC1 | c.963G>T p.A321= | Splice Region (SNP) | VAF 46/101 reads (46%) | catalogued as COSV100873791; called by muse, mutect2, varscan2
- UFL1 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | catalogued as rs773270637, COSV100990079; called by muse, mutect2, varscan2
- UMOD | c.1741-2A>T p.X581_splice | Splice Site (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100208406; called by muse, mutect2, varscan2
- UNC80 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99779689; called by muse, mutect2, varscan2
- USP34 | c.2970C>G p.F990L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101277056, COSV101277342; called by muse, mutect2
- WDR43 | c.1620G>T p.T540= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101332983; called by muse, mutect2, varscan2
- WNT8B | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100649028; called by muse, mutect2, varscan2
- XIRP2 | c.7179C>A p.Y2393* (on ENST00000628543; = p.Y2568* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99743452; called by muse, mutect2, varscan2
- XPOT | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100225569; called by muse, mutect2, varscan2
- ZDHHC2 | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100024877; called by muse, mutect2, varscan2
- ZFHX3 | c.9061G>C p.G3021R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV99212885; called by muse, mutect2, varscan2
- ZFHX4 | c.2770G>T p.V924L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.987); catalogued as COSV99263325; called by muse, mutect2, varscan2
- ZFHX4 | c.5254C>G p.P1752A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99263331; called by muse, mutect2, varscan2
- ZNF182 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV100527074; called by muse, mutect2, varscan2
- ZNF2 | c.845G>T p.R282L (on ENST00000611147 / NM_001291605.2; = p.R269L on NM_021088.4) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99728500, COSV99728701; called by muse, mutect2, varscan2
- ZNF229 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99350464; called by muse, mutect2, varscan2
- ZNF30 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100340576; called by muse, mutect2, varscan2
- ZNF425 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as COSV100955486; called by muse, mutect2, varscan2
- ZNF462 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99472145; called by muse, mutect2, varscan2
- ZNF490 | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV100267371; called by muse, mutect2, varscan2
- ZNF517 | c.936C>G p.S312R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV100743667, COSV63465466; called by mutect2, varscan2
- ZNF518A | c.4437G>T p.W1479C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100283546; called by muse, mutect2, varscan2
- ZNF534 | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99989828; called by muse, mutect2, varscan2
- ZNF669 | c.1136A>G p.N379S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.396); catalogued as COSV100594274; called by muse, mutect2, varscan2
- ZNF674 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV101345037; called by muse, mutect2, varscan2
- ZNF746 | c.271A>T p.R91W | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100502481; called by muse, mutect2, varscan2
- AHCTF1 | c.3067del p.E1023Rfs*10 (on ENST00000366508; = p.E997Rfs*10 on NM_015446.5) | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- ARIH2 | c.494G>A p.W165* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by pindel, varscan2
- BCLAF3 | c.1627del p.Q543Rfs*3 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- FRK | c.1121del p.G374Dfs*8 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- HNF1B | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGLC3 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- MRC1 | c.2856C>A p.Y952* | Nonsense Mutation (SNP) | VAF 55/295 reads (19%) | called by muse, mutect2, varscan2
- MUC2 | c.2912C>A p.T971N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.59); called by muse, mutect2, varscan2
- NRIP2 | c.402_403del p.E135Afs*37 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- OR2T3 | c.498dup p.I167Hfs*11 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- PCDHA11 | c.1709del p.G570Afs*10 | Frame Shift Del (DEL) | VAF 75/301 reads (25%) | called by mutect2, pindel, varscan2
- PCDHB4 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 59/582 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDHGA11 | c.860del p.S287Tfs*49 | Frame Shift Del (DEL) | VAF 59/206 reads (29%) | called by mutect2, pindel, varscan2
- POTEA | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RADIL | c.1399A>T p.I467F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- RXRB | c.1473_1479delinsG p.R492_L493del | In Frame Del (DEL) | VAF 15/61 reads (25%) | called by pindel, varscan2*
- UBE2NL | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- WAS | c.1148del p.P383Lfs*62 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- WASHC4 | c.852del p.F284Lfs*16 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- ZC3H7B | c.-6-10_1delinsG | Splice Site (DEL) | VAF 24/165 reads (15%) | called by pindel, varscan2*
- ZNF84 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.579G>T p.R193= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100622963; called by muse, mutect2, varscan2
- ADGRG5 | c.1446G>C p.L482= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100446426; called by muse, mutect2, varscan2
- ADGRL3 | c.1326C>T p.N442= (on ENST00000506720 / NM_001322402.2; = p.N374= on NM_015236.6) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101547185; called by muse, mutect2, varscan2
- AGRN | c.1707C>T p.S569= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs765720576, COSV101038889; called by muse, mutect2, varscan2
- ATP10A | c.2157C>T p.H719= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs752430251, COSV100791293; called by muse, mutect2, varscan2
- ATP2B2 | c.384C>T p.G128= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as rs369096792; called by muse, mutect2, varscan2
- BAMBI | c.471G>A p.V157= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1357794303, COSV100977505; called by muse, mutect2, varscan2
- BNIP5 | c.192A>G p.P64= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV101465155; called by muse, mutect2, varscan2
- CEACAM18 | c.369C>A p.T123= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs774668788, COSV67282914; called by muse, mutect2, varscan2
- CELSR2 | c.6294C>T p.A2098= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99603959; called by muse, mutect2, varscan2
- CETP | c.399G>A p.E133= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV99570053; called by muse, mutect2, varscan2
- CNR1 | c.1122C>T p.L374= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV62987399; called by muse, mutect2, varscan2
- COP1 | c.933A>C p.T311= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100443374; called by muse, mutect2
- CPS1 | c.2442G>T p.R814= | Silent (SNP) | VAF 57/167 reads (34%) | catalogued as COSV51819620; called by muse, mutect2, varscan2
- CRYBG1 | c.2286A>T p.P762= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100954486; called by muse, mutect2, varscan2
- CYP7A1 | c.198T>A p.V66= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs779020982, COSV56962812; called by muse, mutect2, varscan2
- DAAM2 | c.1767T>C p.S589= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV99225813; called by muse, mutect2, varscan2
- DLG2 | c.321C>G p.G107= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV54679399, COSV99716380; called by muse, mutect2, varscan2
- DOK1 | c.966G>T p.T322= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs998038720, COSV51216221, COSV99284087; called by muse, mutect2, varscan2
- DTX1 | c.1437G>A p.T479= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs148384072; called by muse, mutect2, varscan2
- DVL3 | c.1245C>T p.I415= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs267599712, COSV100493679; called by muse, mutect2, varscan2
- FABP9 | c.225A>G p.T75= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV100986946; called by muse, mutect2, varscan2
- FAM47A | c.657G>T p.P219= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV100649919, COSV60495103; called by muse, mutect2, varscan2
- FAM83G | c.6C>T p.A2= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100525172; called by muse, mutect2, varscan2
- GABRA6 | c.339G>T p.T113= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs113239794, COSV99194560; called by muse, mutect2, varscan2
- GATA3 | c.1096C>A p.R366= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as CM011940, COSV100651029, COSV60515523; called by mutect2, varscan2
- GPSM2 | c.1725A>G p.T575= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV99915300; called by muse, mutect2, varscan2
- GRIN2B | c.276G>T p.R92= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV101663060, COSV101663168; called by muse, mutect2, varscan2
- GUCY2F | c.2478G>T p.R826= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV54306460, COSV99485065; called by muse, mutect2, varscan2
- HCN4 | c.3435C>A p.I1145= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV56088226, COSV99983793; called by muse, mutect2, varscan2
- HDGFL2 | c.120C>T p.Y40= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs746676609, COSV100012242; called by muse, mutect2, varscan2
- HSPA13 | c.669G>T p.V223= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99580059; called by muse, mutect2, varscan2
- IGHV5-51 | c.33G>T p.L11= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- IGKV1D-12 | c.273A>G p.T91= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1249904348; called by mutect2, varscan2
- IGKV2D-30 | c.231T>C p.S77= | Silent (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- IGLC3 | c.201G>T p.A67= | Silent (SNP) | VAF 7/70 reads (10%) | called by mutect2, varscan2
- KIR3DL1 | c.879C>T p.C293= | Silent (SNP) | VAF 102/279 reads (37%) | catalogued as rs747304776; called by muse, mutect2, varscan2
- KRT25 | c.810G>A p.A270= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100379948, COSV56446033; called by muse, mutect2, varscan2
- LEPR | c.687T>G p.V229= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV100756587; called by muse, mutect2, varscan2
- LGR6 | c.2769C>T p.N923= (on ENST00000367278 / NM_001017403.1; = p.N871= on NM_021636.3) | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV99707097; called by muse, mutect2, varscan2
- LHX8 | c.447C>A p.V149= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as COSV53956641, COSV99633835; called by muse, mutect2, varscan2
- LILRB5 | c.1203C>T p.S401= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV100300444; called by muse, mutect2, varscan2
- LIN9 | c.888A>G p.K296= (on ENST00000366808 / NM_001270410.2; = p.K241= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100067507; called by muse, mutect2, varscan2
- LRRN2 | c.591C>A p.G197= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV100912868; called by muse, mutect2, varscan2
- MEST | c.954A>G p.L318= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV99784271; called by muse, mutect2, varscan2
- MOCOS | c.1932G>T p.R644= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99733472; called by muse, mutect2, varscan2
- MPST | c.810C>T p.P270= (on ENST00000341116 / NM_001369904.2; = p.P290= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100353342; called by muse, mutect2, varscan2
- NPR1 | c.2515C>T p.L839= | Silent (SNP) | VAF 95/296 reads (32%) | catalogued as COSV100902033; called by muse, mutect2, varscan2
- OLFML2B | c.1569C>G p.A523= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV99668488; called by muse, mutect2, varscan2
- OR2B11 | c.400C>T p.L134= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV59511873; called by muse, mutect2, varscan2
- OR2J2 | c.225C>G p.T75= | Silent (SNP) | VAF 60/192 reads (31%) | catalogued as COSV101013380, COSV101013429; called by muse, mutect2, varscan2
- OR2W3 | c.897G>T p.G299= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1558359892; called by muse, mutect2, varscan2
- OR51G1 | c.408C>A p.T136= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100429258, COSV58969106; called by muse, mutect2, varscan2
- OR56A4 | c.408C>A p.V136= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV100417585; called by muse, mutect2, varscan2
- PAQR9 | c.1026C>A p.A342= | Silent (SNP) | VAF 36/189 reads (19%) | catalogued as COSV100503815; called by muse, mutect2, varscan2
- PGGHG | c.2097C>T p.S699= | Silent (SNP) | VAF 93/206 reads (45%) | catalogued as rs200720355; called by muse, mutect2, varscan2
- PLAAT5 | c.612C>T p.Y204= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100080500; called by muse, mutect2
- PLXND1 | c.4464T>C p.S1488= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV100139825; called by muse, mutect2, varscan2
- PNMA3 | c.999G>A p.E333= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV64722718; called by muse, mutect2, varscan2
- POPDC2 | c.921A>G p.T307= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as COSV99951028; called by muse, mutect2, varscan2
- PRUNE1 | c.441C>G p.S147= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99639604, COSV99639704; called by muse, mutect2, varscan2
- PTCH2 | c.909C>T p.A303= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100942122; called by muse, mutect2, varscan2
- QSER1 | c.855A>G p.T285= (on ENST00000399302; = p.T414= on NM_001076786.3) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV101234862; called by muse, mutect2, varscan2
- RET | c.2031G>T p.R677= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV100393726; called by muse, mutect2, varscan2
- RPS6KA2 | c.267C>A p.A89= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV55826365, COSV99691104; called by muse, mutect2, varscan2
- RPS6KA2 | c.129C>T p.I43= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs1054380355, COSV99691108; called by muse, mutect2, varscan2
- RPSA | c.765C>T p.P255= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV100088142; called by muse, varscan2
- SASH1 | c.1446A>C p.G482= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100821241; called by muse, mutect2
- SEMA3C | c.759G>A p.R253= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs1038066564, COSV99543103; called by muse, mutect2, varscan2
- SH2B3 | c.1032T>A p.P344= | Silent (SNP) | VAF 61/249 reads (24%) | catalogued as COSV100374297; called by muse, mutect2, varscan2
- SH3BP2 | c.1233G>A p.P411= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs752967350, COSV100696958; called by muse, mutect2, varscan2
- SLC1A6 | c.1149C>T p.T383= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs568967705, COSV99693792; called by muse, mutect2, varscan2
- SLC38A10 | c.954T>G p.P318= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV99917547; called by muse, mutect2, varscan2
- SLITRK3 | c.1183C>A p.R395= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs768253569, COSV53848946, COSV99578768; called by muse, mutect2, varscan2
- STAM2 | c.900C>T p.A300= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV99813099; called by muse, mutect2, varscan2
- TAF4B | c.201G>T p.G67= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99300296; called by muse, mutect2
- TEX55 | c.610C>A p.R204= | Silent (SNP) | VAF 77/198 reads (39%) | catalogued as COSV55210194, COSV99817551; called by muse, mutect2, varscan2
- TGM6 | c.1041C>T p.P347= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99171802; called by muse, mutect2, varscan2
- TMEM132D | c.2583C>T p.I861= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV67161855; called by muse, mutect2, varscan2
- TMPRSS13 | c.798G>T p.L266= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV101471445; called by muse, mutect2, varscan2
- TUBGCP2 | c.1341G>T p.A447= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99427801; called by muse, mutect2, varscan2
- ZFHX4 | c.3916C>A p.R1306= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs748037378, COSV50909309, COSV99259522; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1965A>T p.L655= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV100048235; called by muse, mutect2, varscan2
- ZNF563 | c.262C>A p.R88= | Silent (SNP) | VAF 47/172 reads (27%) | catalogued as COSV53371029, COSV99536620; called by muse, mutect2, varscan2
- ZNF705A | c.273C>G p.S91= | Silent (SNP) | VAF 61/178 reads (34%) | catalogued as COSV100828318; called by muse, mutect2, varscan2
- ZSCAN9 | c.214C>A p.R72= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV52849517, COSV99356443; called by muse, mutect2, varscan2
- AC244258.1 | n.845G>T | RNA (SNP) | VAF 7/38 reads (18%) | catalogued as rs753221894; called by muse, mutect2, varscan2
- AC244258.1 | n.969T>C | RNA (SNP) | VAF 60/163 reads (37%) | catalogued as rs1386860468; called by muse, mutect2, varscan2
- FAM169B | n.584G>A | RNA (SNP) | VAF 10/37 reads (27%) | catalogued as rs201056353, COSV100259854; called by muse, mutect2, varscan2
- MYB | c.1203+1112A>G | Intron (SNP) | VAF 30/94 reads (32%) | catalogued as rs1368855453, COSV100214904; called by muse, mutect2, varscan2
- NPSR1 | c.-1C>A | 5'UTR (SNP) | VAF 31/94 reads (33%) | catalogued as COSV100706464; called by muse, mutect2, varscan2
- SLC25A48 | c.679+29C>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99192035; called by muse, mutect2, varscan2
- SSPOP | n.13213C>T | RNA (SNP) | VAF 3/8 reads (38%) | catalogued as rs1313126152, COSV100947469; called by muse, mutect2
- SSX6P | chrX:48117138 G>T | 3'Flank (SNP) | VAF 62/171 reads (36%) | called by muse, mutect2, varscan2
- TUBB7P | n.416T>A | RNA (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
